TCGA case TCGA-A6-2683 — Colon Adenocarcinoma (TCGA-COAD)
Open-access clinical record from the NCI Genomic Data Commons (Data Release 46.0 - August 10, 2026), part of The Cancer Genome Atlas (TCGA). Disease type: Adenomas and Adenocarcinomas; Primary site: Colon; Tissue source site: Christiana Healthcare. Index date (day 0 for every day count below): diagnosis.
https://portal.gdc.cancer.gov/cases/fafd4576-0709-49e1-926f-ad1ee09907ec

Demographics
Sex at birth: female; Race: white; Ethnicity: not hispanic or latino; Age at index: 57 years; Vital status: Dead; Days to death: 504 days (1.4 years).

Diagnoses (2)
1. Adenocarcinoma, NOS (the primary disease): ICD-O-3 morphology code: 8140/3; ICD-10 code: C18.2; Tissue or organ of origin: Ascending colon; Site of resection or biopsy: Ascending colon; Classification of tumor: primary; Age at diagnosis: 57.1 years (20,871 days); Year of diagnosis: 2009; AJCC staging edition: 6th; AJCC pathologic T: T4; AJCC pathologic N: N0; AJCC pathologic M: M1; AJCC pathologic stage: Stage IV; Prior malignancy: no; Synchronous malignancy: No; Prior treatment: No; Residual disease: R0.
   Pathology details: Consistent pathology review: Yes; Lymph nodes positive: 0; Lymph nodes tested: 25; Lymphatic invasion present: No; Non nodal tumor deposits: No; Vascular invasion present: No.
   Treatment given: Treatment type: Chemotherapy; Therapeutic agents: Fluorouracil; Treatment intent type: Adjuvant; Days to treatment start: 48 days; Days to treatment end: 287 days; Number of cycles: 16; Treatment dose: 10,050 mg; Prescribed dose: 625; Prescribed dose units: mg; Route of administration: Intravenous.
   Treatment given: Treatment type: Chemotherapy; Therapeutic agents: Fluorouracil; Treatment intent type: Adjuvant; Days to treatment start: 48 days; Days to treatment end: 289 days; Number of cycles: 16; Treatment dose: 60,525 mg; Prescribed dose: 4000; Prescribed dose units: mg.
   Treatment given: Treatment type: Chemotherapy; Therapeutic agents: Irinotecan; Treatment intent type: Adjuvant; Days to treatment start: 48 days; Days to treatment end: 287 days; Number of cycles: 12; Treatment dose: 3,365 mg; Prescribed dose: 300; Prescribed dose units: mg; Route of administration: Intravenous.
   Treatment given: Treatment type: Ancillary Treatment; Therapeutic agents: Leucovorin; Treatment intent type: Adjuvant; Days to treatment start: 48 days; Days to treatment end: 287 days; Number of cycles: 16; Treatment dose: 10,050 mg; Prescribed dose: 625; Prescribed dose units: mg; Route of administration: Intravenous.
   Treatment given: Treatment type: Targeted Molecular Therapy; Therapeutic agents: Bevacizumab; Treatment intent type: Adjuvant; Days to treatment start: 105 days; Days to treatment end: 287 days; Number of cycles: 12; Treatment dose: 3,210 mg; Prescribed dose: 275; Prescribed dose units: mg; Route of administration: Intravenous.
   Treatment given: Treatment type: Targeted Molecular Therapy; Therapeutic agents: Bevacizumab; Initial disease status: Progressive Disease; Days to treatment start: 322 days; Days to treatment end: 350 days; Number of cycles: 3; Treatment dose: 900 mg; Prescribed dose: 300; Prescribed dose units: mg; Route of administration: Intravenous.
   Treatment given: Treatment type: Chemotherapy; Therapeutic agents: Fluorouracil; Initial disease status: Progressive Disease; Days to treatment start: 322 days; Days to treatment end: 350 days; Number of cycles: 3; Treatment dose: 1,950 mg; Prescribed dose: 650; Prescribed dose units: mg; Route of administration: Intravenous.
   Treatment given: Treatment type: Chemotherapy; Therapeutic agents: Fluorouracil; Initial disease status: Progressive Disease; Days to treatment start: 322 days; Days to treatment end: 352 days; Number of cycles: 3; Treatment dose: 11,850 mg; Prescribed dose: 3950; Prescribed dose units: mg.
   Treatment given: Treatment type: Ancillary Treatment; Therapeutic agents: Leucovorin; Initial disease status: Progressive Disease; Days to treatment start: 322 days; Days to treatment end: 350 days; Number of cycles: 3; Treatment dose: 1,950 mg; Prescribed dose: 650; Prescribed dose units: mg; Route of administration: Intravenous.
   Treatment given: Treatment type: Chemotherapy; Therapeutic agents: Oxaliplatin; Initial disease status: Progressive Disease; Days to treatment start: 322 days; Days to treatment end: 350 days; Number of cycles: 3; Treatment dose: 420 mg; Prescribed dose: 140; Prescribed dose units: mg; Route of administration: Intravenous.
   Treatment given: Treatment type: Chemotherapy; Therapeutic agents: Mitomycin; Initial disease status: Progressive Disease; Days to treatment start: 443 days (1.2 years); Days to treatment end: 443 days (1.2 years); Number of cycles: 1; Treatment dose: 16 mg; Prescribed dose: 16; Prescribed dose units: mg; Route of administration: Intravenous.
   Recorded as not given: adjuvant Radiation Therapy, NOS.
2. Diagnosis record without a diagnosis name: Tumor of origin: diagnosis 1 of this record; Age at diagnosis: 58.0 years (21,171 days); Days to diagnosis: 300 days; Prior treatment: Yes.
   Treatment given: Treatment type: Pharmaceutical Therapy, NOS.
   Recorded as not given: Radiation Therapy, NOS; Surgery, NOS.

Follow-up (3 entries)
- Day 300 (post initial treatment): Progression or recurrence: Yes; Days to recurrence: 300 days.
- Days to follow up: 472 days (1.3 years); Disease response: With Tumor.
- Days to follow up: 504 days (1.4 years); Disease response: With Tumor.

Molecular and laboratory tests
- CEA: 2614 ng/mL.
- KRAS mutation, nos: Positive; Mutation codon: 12.
- MLH1 (IHC): Normal.
- MSH2 (IHC): Normal.
- MSH6 (IHC): Normal.
- PMS2 (IHC): Normal.
- Microsatellite Instability: Negative.

Other clinical attributes
- Timepoint category: Initial Diagnosis; Weight: 57.5 kg; Height: 166.3 cm; BMI: 20.8.
- Timepoint category: Prior to Diagnosis; Comorbidities: Colon Polyps; Risk factors: Colon Polyps.

Family history
- Relative with cancer history: no.

Biospecimens (4 samples; slide percentages are pathologist estimates recorded by GDC per slide)
- Sample TCGA-A6-2683-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Longest dimension: 1.7; Intermediate dimension: 0.6; Shortest dimension: 0.3.
  Slide TCGA-A6-2683-01A-01-BS1: Section location: Bottom; Percent tumor cells: 90; Percent tumor nuclei: 90; Percent normal cells: 0; Percent necrosis: 5; Percent stromal cells: 5.
  Slide TCGA-A6-2683-01A-01-TS1: Section location: Top; Percent tumor cells: 87; Percent tumor nuclei: 90; Percent normal cells: 0; Percent necrosis: 3; Percent stromal cells: 10.
- Sample TCGA-A6-2683-01Z: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Preservation method: FFPE; Days to sample procurement: 0 days.
- Sample TCGA-A6-2683-10A: Sample type: Blood Derived Normal; Tissue type: Normal; Specimen type: Peripheral Blood NOS.
- Sample TCGA-A6-2683-11A: Sample type: Solid Tissue Normal; Tissue type: Normal; Specimen type: Solid Tissue; Longest dimension: 1.2; Intermediate dimension: 0.8; Shortest dimension: 0.5.

Additional fields from the legacy TCGA clinical forms (Biospecimen Core Resource XML)
- Enrollment form: History neoadjuvant treatment: No; Prospective collection: Yes; Retrospective collection: No; Tumor status: With tumor; Lymph nodes examined: Yes; CEA level pretreatment: 2614; Lymphovascular invasion indicator: No; Microsatellite instability: No; Loci tested count: 4; Loci abnormal count: 0; KRAS gene analysis indicator: Yes; KRAS mutation found: Yes; BRAF gene analysis indicator: No; History colon polyps: Yes; Colon polyps at procurement indicator: No; Mismatch rep proteins tested by IHC: Yes.
- Loss expression of mismatch repair proteins by ihc results: Mismatch rep proteins loss IHC: MLH1-Expressed; Mismatch rep proteins loss IHC: MSH2-Expressed; Mismatch rep proteins loss IHC: PMS2-Expressed; Mismatch rep proteins loss IHC: MSH6-Expressed.
- Drug treatment 1: Regimen number: 3; Pharmaceutical therapy drug name: Mitomycin C; Therapy regimen: Progression.
- Drug treatment 1, Route of administrations: Route of administration: IV.
- Drug treatment 2: Regimen number: 1.
- Drug treatment 3: Regimen number: 2; Therapy regimen: Progression.
- Drug treatment 4: Regimen number: 1; Pharmaceutical therapy drug name: Avastin.
- Drug treatment 6: Regimen number: 2; Pharmaceutical therapy drug name: 5 FU; Therapy regimen: Progression.
- Drug treatment 8: Regimen number: 1; Pharmaceutical therapy drug name: 5 FU.
- Drug treatment 9: Regimen number: 1; Pharmaceutical therapy drug name: Levcovorin.
- Drug treatment 10: Regimen number: 2; Pharmaceutical therapy drug name: Avastin; Therapy regimen: Progression.
- Follow-up form 1: Tumor status: With tumor; New tumor event diagnosis indicator: Yes.
- Follow-up form 1, New tumor event: New tumor event surgery: No; New tumor event radiation treatment: No; New tumor event pharmaceutical treatment: Yes.

Curated follow-up endpoints (TCGA Pan-Cancer Clinical Data Resource, Liu et al., Cell 2018; times are days from initial pathologic diagnosis to the event or to last contact): overall survival: event (deceased), 504 days; disease-specific survival: event (death attributed to the disease, the Clinical Data Resource's approximation), 504 days; progression-free interval: event (progression, recurrence, new primary tumor or death with tumor), 300 days.

Tumor purity and ploidy (ABSOLUTE, TCGA Pan-Cancer Atlas; aliquot TCGA-A6-2683-01A-01D-1549-01): tumor purity 0.85, ploidy 3.88, whole-genome doublings 2.
